TARGET case TARGET-10-PARTJL — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3d506fa5-d244-5605-9f80-d94fec63feb5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 2.9 years (1,060 days); Year of diagnosis: 2008; Days to last follow up: 968 days (2.7 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (2 entries)
- Days to follow up: 509 days (1.4 years); Days to first event: 509 days (1.4 years); First event: Relapse.
- Days to follow up: 968 days (2.7 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2010.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 34.7 ×10³/µL.
- Day 8: Bone Marrow blast count 15%; Minimal Residual Disease (Flow Cytometry) 8.3%.
- Day 15: Bone Marrow blast count 3%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (3 samples)
- Sample TARGET-10-PARTJL-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARTJL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARTJL-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 968
- WBC at Diagnosis: 34.7
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 8.3
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 15
- BMA Blasts Day 15: 3
- BMA Blasts Day 29: 0
- Down Syndrome: No
- DNA Index: 1.1412
- Alternate Therapy: Chemotherapy
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
